Gene-level copy-number profile of tumor specimen C3L-01664-01 from CPTAC case C3L-01664, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 75.6 years (27,611 days).
Specimen C3L-01664-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 889a3cdf-15f7-42c2-9db2-bd2862b15b95.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01664-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/25caa801-df3c-42e3-924d-21ab9aa396f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,344; copy number 2: 49,705; copy number 3: 8; copy number 4: 3,819; copy number 6: 2,524; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,525 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–248,937,043, 2,524 genes, copy number 6 (broad region; genes not listed).
- chr8:39,451,045–39,522,852, 1 gene, copy number 7: ADAM3A.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
